Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4885, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4885-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY EN BLOC LYMPH NODES:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN
NUCLEAR GRADE 3 (6.0 CM).

TUMOR FOCALLY INVADES THE RENAL SINUS FAT.

LYMPHOVASCULAR INVASION PRESENT.

Vascular and soft tissue margins, no tumor present.

Ureteral margin, no tumor present.

No lymph nodes identified.

(B) LEFT ADRENAL:

METASTATIC RENAL CELL CARCINOMA.

GROSS DESCRIPTION

(A) RIGHT KIDNEY EN BLOC LYMPH NODES - A nephrectomy specimen (23.0 x 14.0 x 6.0 cm, overall measurement) with kidney (13.0 x 8.0 x 5.0 cm) and attached 11.0 cm segment of ureter (0.5 cm in circumference).

A tumor (6.0 x 5.0 x 4.0 cm) is present in the lower pole and mid pole of the kidney. It is mostly tan, focally yellow with myxoid areas. The tumor is confined to the kidney and does not involve perinephric fat. There are focal areas where possible renal sinus invasion may be present. The renal pelvis is tan and smooth. The uninvolved renal parenchyma appears unremarkable. The hilar vessels are not involved by tumor.

SECTION CODE: A1, hilar vascular margins and ureteral margin; A2-A7, tumor and renal sinus; A8, tumor and renal pelvis; A9-A10, tan portion of tumor; A11-A12, yellow portion of tumor; A13-A14, myxoid areas of tumor; A15, uninvolved renal parenchyma; A16, tumor to perinephric fat; A17, one possible lymph node.

(B) LEFT ADRENAL - An adrenal gland with surrounding fatty tissue (5.0 x 2.0 x 1.5 cm). Cut section reveals a tan-yellow-red, well-circumscribed mass (1.0 x 1.0 x 1.0 cm).

INK CODE: Blue - surrounding adrenal tissue.

SECTION CODE: B1, adrenal vein margin; B2-B4, adrenal tumor; B5, uninvolved adrenal parenchyma.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123, T-B3000, M-83126

Source: NCI Genomic Data Commons file 5c256e5e-7195-451b-a117-31b6450d6764 (TCGA-CJ-4885.D14A17D3-E376-4F25-983C-88939604390E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).